Surgical pathology report (de-identified scan), TCGA case TCGA-23-1023, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-23-1023-01A (Primary Tumor).

[page 1 of 4]
SURGICAL
PATIENT:
Hospital
Date of B:

PATH #
A/S:
Rec:
Col:

Location:
Pathologist:
Assistant:
Attending MD:
Ordering MD:
Copies To:

DIAGNOSIS:

High grade mullerian derived adenocarcinoma involving:

- left and right ovaries (tumors approx. 2.5 cm and 3.0 cm, respectively) (spec #2,3)
- bilateral adnexal soft tissues and serosal surfaces (spec #2,#3)
- omentum extensively ("omental cake") (spec #4)
- uterine serosa (spec #5)
- cul de sac tumor (spec #1)
- distal sigmoid serosa (spec #7)
- small bowel serosa (spec #8)
- presacral tumor (spec #9)
- tumor associated necrosis, psammomatous calcifications, serositis (multiple sites), desmoplastic reaction, and adhesions
- tumor in lymphovascular channels
- see comment

ADDITIONAL FINDINGS include:

- Fallopian tubes with atrophic changes and serositis with mesothelial cell hyperplasia, paratubal cystic rests (left); no intramural tumor is seen
- Ovaries with corpora albicantia
- Uterus with benign atrophic endometrium with cystic glands (cystic atrophy), adenomyosis/adenomyoma, leiomyoma, vascular calcinosis, and benign cervix with nabothian cysts, microcysts
- Appendix with hemorrhagic serositis, inflammation, reactive mesothelial cells, patent lumen, and intact mucosa; no tumor seen (spec #6)

Comment: The tumor shows combinations of solid, cystic, and papillary growth patterns. Tumor in all of the affected tissues shows high grade features that include large nuclei, anisonucleosis, prominent nucleoli, tumor giant cells, and frequent mitotic figures. While the ovaries are not markedly enlarged, tumor replaces at least approximately half of each ovary. The histology is consistent with ovarian primaries but the possibility of a peritoneal primary is not excluded. A portion of omental tumor was submitted for clonogenic assay. Results will be reported separately

(continued on next page)□

Page: 2

THIS CASE WAS DISCUSSED

HISTORY: Ovarian carcinoma

MICROSCOPIC:

See Diagnosis.

GROSS:

1: CUL DE SAC TUMOR

Labeled with the patient's name, labeled "cul-de-sac tumor", and received in formalin is an aggregate of tan-pink, soft, friable,

[page 2 of 4]
focally hemorrhagic tissue measuring 3.5 x 3.2 x 1.5 cm. Representative sections are submitted.

A. 3

2: LEFT ADNEXA

Labeled with the patient's name, labeled "left adnexa", and received in formalin is an ovary with attached fallopian tube and adnexal soft tissues. The entire specimen measures 6.5 x 4.0 x 2.0 cm. The fallopian tube including fimbriated end measures 5.2 cm in length and ranges from 0.5 to 1.2 cm in diameter. The serosal surface of the fallopian tube is pink and smooth. On section the tube lumen is 0.2 cm in diameter. No luminal or mural lesions are seen. The attached mesosalpingeal tissue has multiple, tan-pink nodules from 0.3 and 0.5 cm. The ovary measures 2.5 x 1.8 x 0.8 cm in maximum dimensions and has a tan to yellow bosselated serosal surface. Cut sections of the ovary show a tan-pink friable lesion with papillary-like structures measuring 1.5 x 0.9 x 0.5 cm. The remainder of the cut surface of the ovary is tan-pink; no additional lesions are seen. Representative sections are submitted.

B. Fallopian tube - 3

C. Soft tissue with tan nodules - 2

D-F. Ovary - 1 each

3: RIGHT ADNEXA

Labeled with the patient's name, labeled "right adnexa", and received in formalin is an ovary with attached fallopian tube and adnexal soft tissue. The entire specimen measures 6.0 x 5.0 x 2.5 cm. The fallopian tube with fimbriated end measures 4.5 cm in length and 0.5 cm in diameter. The serosal surface of the fallopian tube is tan-pink and smooth. At the proximal end of the fallopian tube, there is a tan, soft, friable nodule measuring 1.3 x 0.7 x 0.5 cm. The mesosalpinx soft tissue is tan-pink and shows multiple tan-white, soft, friable nodules ranging from 0.2 up to 0.6 cm. Cut sections through the fallopian tube reveal a small patent lumen. No luminal or mural lesions are seen. The ovary measures 4.5 x 4.0 x 2.5 cm in maximum dimensions. The serosal surface is tan-pink and focally hemorrhagic with multiple tan-white, soft, friable nodules ranging from 0.1 up to 0.5 cm. Cut sections through the ovary reveal a solid and cystic tumor mass measuring 3.0 x 2.5 x 2.0 cm. The solid areas are tan to yellow and appear papillary. A small portion of residual ovarian parenchyma is seen at the periphery. Representative sections are submitted.

G. Fallopian tube - 3

continued on next page)□

Page: 3

H. Soft tissue with tan-white nodules - 2

I. Ovary - 2

J,K. Ovary with tumor - 1 each

4: OMENTUM

Labeled with the patient's name, labeled "omentum", and received fresh in the Operating Room for intraoperative frozen section consultation and subsequently fixed in formalin is a 60 gram portion of omentum measuring 45.0 x 11.0 x 2.5 cm. Almost the entire omentum is firm and replaced by tan-white, firm tumor. Representative sections are submitted.

L. Frozen section remnant #1 - 1

M-O.1,2,1

5: UTERUS

[page 3 of 4]
Labeled with the patient's name, labeled "uterus", and received in formalin is an 80 gram uterus with attached cervix. The uterus is symmetric and measures 7.5 cm from fundus to ectocervix, 5.0 cm from cornu to cornu, and up to 4.0 cm from anterior to posterior serosa. The uterine serosa is partially smooth and partially shaggy with multiple tan, soft, friable tumor deposits. The tumorous tissue on the posterior serosa measures approximately 5.0 x 2.0 x 1.3 cm. The tumorous tissue on the anterior serosa is multifocal with deposits ranging from 0.8 and 1.5 cm in greatest dimension. The cervix is about 3.5 cm long and has a maximum diameter of 2.2 cm in the ectocervical region. Attached to the ectocervix, there is a 0.2 cm portion of vaginal mucosa. The ectocervical mucosa is tan and smooth without grossly evident lesions. The external os is 1.0 cm in diameter and patent. The uterus is incised on both sides in the Operating Room. The cervical transformation zone is indistinct. The endocervical canal is 2.5 cm long and lined by tan, grossly unremarkable mucosa. Cut sections of the cervix are unremarkable. The endometrial cavity is 3.6 cm long and 3.0 cm in width. The endometrium is tan and ranges from 0.2 to 0.3 cm in thickness. No endometrial lesions are seen. Within the uterus, there is a submucosal leiomyoma measuring 1.5 x 1.5 x 0.7 cm. Cut sections through the leiomyoma show a firm, solid, tan-white cut surface with a whorled configuration without hemorrhage or necrosis. The uterine wall has a maximum thickness of 1.6 cm. The myometrium is grossly unremarkable. Representative sections are submitted.

- P. Anterior cervix - 1
- Q. Posterior cervix - 1
- R. Anterior lower uterine segment - 1
- S. Posterior lower uterine segment - 1
- T. Anterior uterine corpus - 1
- U. Posterior uterine corpus - 1
- V. Leiomyoma - 1
- W,X. Posterior serosal tumor - 1 each
- Y,Z. Anterior serosal tumor - 1 each

6: APPENDIX

Labeled with the patient's name, labeled "appendix", and received in formalin is an appendix measuring 6.4 x 0.7 x 0.5 cm with attached adipose tissue measuring 2.0 cm in width. The serosa is smooth and shiny and the attached adipose tissue is soft. Sectioning reveals a
(continued on next page)□

Page: 4

patent lumen measuring up to 0.3 cm in diameter. No lesions are identified. Representative sections are submitted.

- A2. Base, mid portion and tip - 3

7: SIGMOID DISTAL

Labeled with the patient's name, labeled "sigmoid implant", and received in formalin is a tan-pink, soft, tissue measuring 0.6 x 0.3 x 0.2 cm. The entire specimen is submitted.

- B2. 1

8: SMALL BOWEL

Labeled with the patient's name, labeled "small bowel", and received in formalin are three tan, soft, tissues measuring 0.4, 0.8, and 0.8 cm in greatest dimension, respectively. The entire specimen is submitted.

- C2. 4

9: PRESACRAL TUMOR

Labeled with the patient's name, labeled "presacral tumor", and

[page 4 of 4]
received in formalin are three tan-pink, soft, tissues measuring 0.6, 0.8, and 0.9 cm in greatest dimension, respectively. The entire specimen is submitted.

D2. 5

Gross dictated by:

OPERATIVE CALL

OPERATIVE CONSULT (GROSS):

- Omentum: Extensive tumor
- Tumor also in right and left ovaries and involves uterine anterior and posterior serosa (posterior more than anterior)
- Small uterine submucosal leiomyoma
- Omental tumor taken for clonogenic assay
- Small portion of each ovary was submitted to s lab

OPERATIVE CONSULT (FROZEN):

Specimen #4, FS#1, OMENTUM:

- High-grade carcinoma consistent with Mullerian primary

Gross dictated by

Special Studies: Frozen Section, clonogenic assay
See Also:

Pathologist

I, _____, the pathologist of record, have
(continued on next page) ☐

Page: 5

personally examined the specimen, interpreted the results, reviewed this report and signed it electronically.

Date Finalled:

Source: NCI Genomic Data Commons file f8646602-bc0c-4883-8d60-dd9c4c71d1a5 (TCGA-23-1023.98EBC356-C54E-4C1E-9726-BA61397DDA38.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).